Somatic mutation profile of tumor specimen 0DQU50 from CCDI case PBCFIL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 4.1 years (1,501 days).
Specimen 0DQU50: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8961ac1a-0bdb-4bf5-b357-53fcf402138f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQU5B (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/548e0cec-6057-46ae-9e13-92f14641704e

The open-access MAF lists 42 somatic variants for this specimen: 24 protein-altering or splice-affecting, 12 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 12, Intron 4, Nonsense Mutation 2, Splice Site 2, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1605C>G p.N535K | Missense Mutation (SNP) | VAF 481/559 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519792, COSV52800481, COSV52801581; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AKAP11 | c.3374A>G p.K1125R | Missense Mutation (SNP) | VAF 201/595 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1341751173; called by muse, mutect2, varscan2
- DNAH14 | c.5089G>A p.V1697I (on ENST00000445597; = p.V2102I on NM_001367479.1) | Missense Mutation (SNP) | VAF 231/609 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.177); catalogued as rs763402081, COSV70532867; called by muse, mutect2, varscan2
- HCN1 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 52/766 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1333872397, COSV100298381, COSV57492101, COSV57537055; called by muse, mutect2
- LAD1 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 66/732 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs961881251; called by muse, mutect2
- PKD1L1 | c.6074G>A p.R2025Q | Missense Mutation (SNP) | VAF 212/739 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs372219419; called by muse, mutect2, varscan2
- SYNE1 | c.16429A>G p.M5477V (on ENST00000367255 / NM_182961.4; = p.M5406V on NM_033071.3) | Missense Mutation (SNP) | VAF 279/711 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1435996818; called by muse, mutect2, varscan2
- TAS1R2 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 46/569 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); catalogued as rs549094114, COSV64744794, COSV64746457; called by muse, mutect2
- ABRAXAS2 | c.1140G>T p.L380F | Missense Mutation (SNP) | VAF 26/450 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.885); called by muse, mutect2
- ATP8B4 | c.3527A>G p.K1176R | Missense Mutation (SNP) | VAF 40/499 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.013); called by muse, mutect2
- HPCAL1 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 166/835 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- HUWE1 | c.6235G>T p.V2079L | Missense Mutation (SNP) | VAF 27/292 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2
- IDO2 | c.210C>A p.S70R (on ENST00000389060; = p.S83R on NM_194294.2) | Missense Mutation (SNP) | VAF 48/1407 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); called by muse, mutect2
- IL11 | c.469C>G p.P157A | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2
- LACTB | c.1362G>A p.W454* | Nonsense Mutation (SNP) | VAF 190/584 reads (33%) | called by muse, mutect2, varscan2
- LMBR1L | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 145/763 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- PALD1 | c.622A>G p.I208V | Missense Mutation (SNP) | VAF 58/541 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- PZP | c.236A>G p.E79G | Missense Mutation (SNP) | VAF 239/1128 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- RBM42 | c.684+1G>T p.X228_splice | Splice Site (SNP) | VAF 24/298 reads (8%) | called by muse, mutect2
- SLC35F4 | c.620T>C p.I207T (on ENST00000339762 / NM_001352015.2; = p.I171T on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 209/554 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- SPTBN2 | c.3749G>T p.R1250L | Missense Mutation (SNP) | VAF 243/1052 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TCF24 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT tolerated (0.37); called by muse, mutect2, varscan2
- TTC9 | c.406+1G>T p.X136_splice | Splice Site (SNP) | VAF 35/108 reads (32%) | called by muse, mutect2, varscan2
- ZNF37A | c.1057A>T p.K353* | Nonsense Mutation (SNP) | VAF 184/497 reads (37%) | called by muse, mutect2, varscan2
- ATP13A5 | c.612A>G p.L204= | Silent (SNP) | VAF 174/627 reads (28%) | called by muse, mutect2, varscan2
- CNTNAP1 | c.1215C>T p.D405= | Silent (SNP) | VAF 170/657 reads (26%) | catalogued as COSV52850129; called by muse, mutect2, varscan2
- DDX47 | c.1002G>T p.V334= | Silent (SNP) | VAF 205/967 reads (21%) | called by muse, mutect2, varscan2
- DEPDC4 | c.486C>A p.G162= | Silent (SNP) | VAF 140/975 reads (14%) | catalogued as COSV54554380; called by muse, mutect2, varscan2
- IQCA1 | c.813A>G p.E271= | Silent (SNP) | VAF 280/1052 reads (27%) | catalogued as rs201005211, COSV99609683; called by muse, mutect2, varscan2
- LETMD1 | c.30G>T p.R10= | Silent (SNP) | VAF 62/438 reads (14%) | called by mutect2, varscan2
- OR5L1 | c.432G>A p.L144= | Silent (SNP) | VAF 268/890 reads (30%) | called by muse, mutect2, varscan2
- PCDHB4 | c.1651C>T p.L551= | Silent (SNP) | VAF 10/278 reads (4%) | catalogued as COSV52023677; called by muse, mutect2
- PDCD4 | c.216C>T p.G72= | Silent (SNP) | VAF 37/498 reads (7%) | called by muse, mutect2
- SLC17A1 | c.816T>C p.F272= | Silent (SNP) | VAF 20/791 reads (3%) | catalogued as rs902289445; called by muse, mutect2
- WASHC4 | c.2073T>C p.H691= | Silent (SNP) | VAF 220/966 reads (23%) | called by muse, mutect2, varscan2
- WSCD2 | c.513C>T p.G171= | Silent (SNP) | VAF 110/559 reads (20%) | catalogued as rs766850790, COSV54579301; called by muse, mutect2, varscan2
- AC107023.1 | n.25+3008A>T | Intron (SNP) | VAF 153/694 reads (22%) | called by muse, mutect2, varscan2
- ASGR2 | c.*38G>T | 3'UTR (SNP) | VAF 14/254 reads (6%) | called by muse, mutect2
- BCAN | c.2209+54_2209+55dup | Intron (INS) | VAF 45/112 reads (40%) | called by mutect2, varscan2
- CHRNA7 | c.56-18G>T | Intron (SNP) | VAF 86/210 reads (41%) | called by muse, mutect2, varscan2
- POLR1G | c.22+76G>A | Intron (SNP) | VAF 57/164 reads (35%) | called by muse, mutect2, varscan2
- ZYX | chr7:143380048 C>T | 5'Flank (SNP) | VAF 175/653 reads (27%) | catalogued as rs939101584; called by muse, mutect2, varscan2
